Gene-level copy-number profile of tumor specimen TCGA-A2-A4RW-01A from TCGA case TCGA-A2-A4RW, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 49.4 years (18,060 days).
Specimen TCGA-A2-A4RW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.82aeac9e-e169-41dc-8580-4165d4ea0ac9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A2-A4RW-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0862c140-e6a5-4bf3-acd8-e5c0d52f660c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 14,126; copy number 2: 38,650; copy number 3: 5,157; copy number 4: 1,518; copy number 5: 260; copy number 6: 57; copy number 7: 4; copy number 8: 41.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A2-A4RW-01A-21D-A25N-01): tumor purity 0.49, ploidy 1.92, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:87,859,158–88,259,372, 7 genes: KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 362 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:37,133,489–37,859,592, 30 genes, copy number 5 (within-gene range 3–5): AL031430.1, AL353604.1, MIR4255, RNU6-636P, RNA5SP43, RPS29P6, LINC01137, ZC3H12A, MIR6732, MEAF6, MIR5581, SNIP1, FTH1P1, AL034379.1, DNALI1, GNL2, AL513220.1, RSPO1, C1orf109, CDCA8, EPHA10, Y_RNA, ACTN4P2, AL929472.1, MANEAL, AL929472.3, YRDC, C1orf122, MTF1, AL929472.4.
- chr1:43,525,187–44,390,823, 36 genes, copy number 5: PTPRF, KDM4A, AL451062.2, KDM4A-AS1, ST3GAL3, ST3GAL3-AS1, U6, AL451062.1, MIR6079, SHMT1P1, ARTN, AL357079.1, AL357079.3, IPO13, AL357079.2, DPH2, ATP6V0B, B4GALT2, CCDC24, SLC6A9, AL139220.2, AL139220.1, KRT8P47, RN7SL479P, KLF17, AL356653.1, KLF18, AL359839.1, Y_RNA, OOSP1P1, AL035417.1, AL035417.2, DMAP1, ERI3, ERI3-IT1, RNU6-369P.
- chr1:45,493,866–46,370,955, 34 genes, copy number 5: CCDC163, MMACHC, PRDX1, HMGB1P48, AKR1A1, AL355480.3, AL355480.1, NASP, AL355480.2, AL355480.4, CCDC17, GPBP1L1, RPS15AP10, AL604028.2, TMEM69, IPP, AL604028.1, AL603882.1, MAST2, TMA16P2, PIK3R3, P3R3URF-PIK3R3, AL358075.1, AL358075.3, AL358075.2, TSPAN1, P3R3URF, POMGNT1, LURAP1, RAD54L, LRRC41, UQCRH, NSUN4, AL122001.1.
- chr1:47,688,463–50,023,954, 26 genes, copy number 5 (within-gene range 3–5): LINC01738, TRABD2B, AL691459.1, AC096541.1, LINC02794, AL356289.1, CYP46A4P, SKINT1L, AL356289.2, AL109659.1, SLC5A9, AL109659.2, AL109659.3, SPATA6, PPP1R8P1, RNU6-723P, AL356968.2, RNU4-61P, AL356968.1, AGBL4, AL391844.1, BEND5, AL645507.1, AC099788.1, AGBL4-AS1, AGBL4-IT1.
- chr1:54,998,933–59,296,491, 57 genes, copy number 6 (within-gene range 3–6): BSND, PCSK9, USP24, MIR4422HG, GYG1P3, MIR4422, AL603840.1, GOT2P1, MTCO2P34, RN7SKP291, RNU6-830P, Y_RNA, LINC01755, LINC01753, PIGQP1, AL353681.1, AC119674.1, AC119674.2, RPSAP20, LINC01767, PLPP3, RPL21P23, RPL23AP85, AC099789.1, PRKAA2, FYB2, AL360295.1, C8A, C8B, AL161740.1, DAB1, AL390243.1, RPS20P5, DAB1-AS1, HNRNPA1P6, RPS26P15, AL445193.2, AL445193.1, AL357373.1, OMA1, AL035411.3, AL035411.2, RN7SL713P, TACSTD2, AL035411.1, MYSM1, AL136985.3, JUN, LINC01135, AL136985.2, AL136985.1, LINC02777, LINC01358, PHBP3, AL592431.2, AL592431.1, HSD52.
- chr6:11,414,636–12,585,404, 20 genes, copy number 5: AL445430.2, AL445430.1, RNU1-64P, THAP12P5, TMEM170B, AL357518.1, Metazoa_SRP, AL022724.1, ADTRP, AL022724.3, AL022724.2, AMD1P4, AL157373.1, AL157373.2, HIVEP1, EDN1, SUMO2P12, RN7SKP293, RPL15P3, LINC02530.
- chr6:17,224,243–17,557,790, 4 genes, copy number 7 (within-gene range 4–7): AL136305.1, RBM24, AL034372.1, CAP2.
- chr6:22,085,544–22,147,193, 2 genes, copy number 5: RN7SKP240, NBAT1.
- chr15:95,280,753–101,933,350, 153 genes, copy number 5–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 14,126. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
